Somatic mutation profile of tumor specimen TCGA-06-0151-01A (aliquot TCGA-06-0151-01A-01D-1491-08) from TCGA case TCGA-06-0151, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 32.7 years (11,956 days).
Specimen TCGA-06-0151-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 967604f3-1ba8-4483-a581-328c1746f4ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0151-10A (Blood Derived Normal), aliquot TCGA-06-0151-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ede4ff1e-dca1-4683-bd65-dcfe3cc5ef77

The open-access MAF lists 18 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 14, Nonsense Mutation 2, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACP4 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as rs201115271, COSV54517784; called by muse, mutect2, varscan2
- ALB | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs748640859, COSV55735636; called by muse, mutect2, varscan2
- CFHR5 | c.737C>G p.P246R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV56824194; called by muse, mutect2, varscan2
- DDX59 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58752814; called by muse, mutect2, varscan2
- KRT222 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 18/145 reads (12%) | catalogued as rs775938117, COSV67498576; called by muse, mutect2, varscan2
- MYO1A | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 62/194 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs754238164, COSV55655387; called by muse, mutect2, varscan2
- NFIB | c.805A>G p.S269G | Missense Mutation (SNP) | VAF 272/469 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV66627276; called by muse, mutect2, varscan2
- NLGN1 | c.1910G>C p.R637T | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs941998738, COSV64339592, COSV64340030; called by muse, mutect2, varscan2
- PCDHB5 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.392); catalogued as rs782174072, COSV50658191; called by muse, varscan2
- PRKRA | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs148050153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD54L2 | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as COSV56579873; called by muse, mutect2, varscan2
- SLC35E4 | c.765G>T p.W255C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1267718650, COSV55899351; called by muse, mutect2, varscan2
- TNN | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV53429958; called by muse, mutect2, varscan2
- ZNF470 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 57/167 reads (34%) | catalogued as COSV57969745; called by muse, mutect2, varscan2
- ZRANB3 | c.2789C>A p.S930Y | Missense Mutation (SNP) | VAF 82/358 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV51507492; called by muse, mutect2, varscan2
- SELPLG | c.127del p.A43Pfs*7 | Frame Shift Del (DEL) | VAF 57/204 reads (28%) | called by mutect2, pindel, varscan2
- KRT7 | c.1011C>T p.A337= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs368567294; called by muse, mutect2, varscan2
